Gene-level copy-number profile of tumor specimen C3L-00598-02 (profiled together with C3L-00598-03) from CPTAC case C3L-00598, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 61.5 years (22,466 days).
Specimen C3L-00598-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3471834a-5b01-4f22-8a54-3fc60e737b80.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00598-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/8f89ae7e-7add-4449-9fc0-b5e762d0571d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 87; copy number 1: 59; copy number 2: 9,622; copy number 3: 2,297; copy number 4: 44,432; copy number 5: 1,902; copy number 6: 4.

Homozygous deletions (total copy number 0; autosomes only): 87 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–2): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr9:21,077,104–22,214,672, 53 genes: IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr9:79,036,413–79,391,759, 3 genes: KRT18P24, AL512634.1, CHCHD2P9.
- chr18:50,795,120–51,845,628, 17 genes: MRO, HNRNPA3P16, RPL17P46, ME2, Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1, RSL24D1P9, AC027216.1, RPS8P3.
- chr18:69,212,277–69,961,803, 8 genes: AC090337.1, AC026585.1, DOK6, AC119868.1, AC119868.2, AC068254.2, AC068254.1, CD226.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 59. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
